CCDI case PBBKBK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/47553e3f-595e-47aa-aadd-e4f6f093a513

Demographics
Sex at birth: male; Race: asian; Vital status: Alive.

Diagnoses (1)
1. Choroid plexus carcinoma: ICD-O-3 morphology code: 9390/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.3 years (1,214 days).

Biospecimens (3 samples)
- Sample 0DAN5Z: Tissue type: Normal; Specimen type: Solid Tissue.
- Sample 0DAN6H: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DAN6R: Tissue type: Tumor; Specimen type: Solid Tissue.
